Somatic mutation profile of tumor specimen TCGA-CV-5444-01A (aliquot TCGA-CV-5444-01A-02D-1512-08) from TCGA case TCGA-CV-5444, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.8 years (23,650 days).
Specimen TCGA-CV-5444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5424905f-9669-4803-85c7-0ab60fc636c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5444-11A (Solid Tissue Normal), aliquot TCGA-CV-5444-11A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e6f207e-a102-4db9-a944-296fa785f318

The open-access MAF lists 140 somatic variants for this specimen: 95 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 41, Nonsense Mutation 6, Splice Site 2, RNA 2, Splice Region 2, 3'UTR 1, Frame Shift Del 1, 5'Flank 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.457+1G>A p.X153_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | hotspot (GDC flag); catalogued as CS041518, CS941435, COSV58685123, COSV58690553, COSV58696311; called by muse, mutect2, varscan2
- MYO18B | c.3052C>A p.P1018T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV100123667, COSV59127388; called by muse, varscan2
- TGFBR2 | c.1397-1G>A p.X466_splice | Splice Site (SNP) | VAF 16/92 reads (17%) | catalogued as rs1553631693, CS064462, COSV55464532; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.416_424del p.K139_P142delinsT | In Frame Del (DEL) | VAF 7/51 reads (14%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAM17 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs911483021, COSV100176265; called by muse, mutect2, varscan2
- AHNAK2 | c.9293C>T p.T3098M | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs374657511, COSV60907227; called by muse, mutect2, varscan2
- AP1G1 | c.2334C>G p.I778M | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV100250424; called by muse, mutect2
- ARHGEF17 | c.3843C>G p.L1281= | Splice Region (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99735639; called by muse, mutect2
- ATP5PB | c.96G>C p.R32S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV99330823; called by muse, mutect2
- BAZ2B | c.3482C>G p.A1161G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99680976; called by muse, mutect2
- C19orf18 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100071789; called by muse, mutect2, varscan2
- CABLES2 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs576077601, COSV54158398; called by muse, mutect2, varscan2
- CDC42BPA | c.3941G>A p.C1314Y (on ENST00000334218 / NM_001366019.2; = p.C1301Y on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505106; called by muse, mutect2
- CELSR2 | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as rs763391847, COSV99603845; called by muse, mutect2, varscan2
- CFAP94 | c.1318G>C p.E440Q (on ENST00000320267 / NM_001352064.2; = p.E446Q on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as rs1306808137, COSV99060654; called by muse, mutect2
- CNOT8 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99597182; called by muse, mutect2, varscan2
- COIL | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99538173; called by muse, mutect2, varscan2
- CRKL | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62882763; called by muse, mutect2
- CSTF1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53859511; called by muse, mutect2, varscan2
- CTNND2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773745550, COSV58868584; called by muse, mutect2, varscan2
- CTTN | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100097707; called by muse, mutect2
- CYP4A22 | c.1463C>G p.P488R | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53740244; called by muse, varscan2
- DGKZ | c.930G>A p.M310I (on ENST00000454345 / NM_001105540.2; = p.M121I on NM_003646.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100551410; called by muse, mutect2, varscan2
- DGKZ | c.2944G>T p.E982* (on ENST00000454345 / NM_001105540.2; = p.E794* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100551413; called by muse, mutect2, varscan2
- DICER1 | c.4981C>T p.H1661Y | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.95); catalogued as COSV100602109; called by muse, mutect2, varscan2
- DNAJC6 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1418377722, COSV99674831; called by muse, mutect2
- DYNC1H1 | c.12427C>T p.R4143C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1316357429, COSV64142763; called by muse, mutect2
- FAT4 | c.1260C>G p.I420M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101272354, COSV67888840; called by muse, mutect2, varscan2
- FIGNL1 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100794895; called by muse, mutect2, varscan2
- FMOD | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100724550; called by muse, mutect2
- FOXG1 | c.573G>C p.M191I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100486807, COSV57396030; called by muse, mutect2
- FOXO1 | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101091998; called by muse, mutect2, varscan2
- FREM2 | c.7009T>A p.F2337I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99748784; called by muse, mutect2, varscan2
- FSCN3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99133748; called by muse, mutect2, varscan2
- GSDMD | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV99369360; called by muse, mutect2, varscan2
- GYPB | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV99301863, COSV99302330; called by muse, mutect2, varscan2
- HCAR3 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV100811615, COSV63674833; called by muse, mutect2
- HDAC5 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99291242; called by muse, mutect2, varscan2
- HTR6 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244776239, COSV99230163; called by muse, mutect2
- IL17RE | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV99925008; called by muse, mutect2, varscan2
- INPP5B | c.1268G>A p.R423Q (on ENST00000373023; = p.R343Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs893699387, COSV100886486; called by muse, mutect2
- KIF18B | c.1242G>T p.Q414H (on ENST00000593135 / NM_001265577.2; = p.Q426H on NM_001264573.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV100192177, COSV59274253; called by mutect2, varscan2
- KMT2C | c.10925C>G p.S3642C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100071874; called by muse, varscan2
- KMT2C | c.10868C>G p.S3623* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100071878; called by muse, varscan2
- KRT4 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99542937; called by muse, mutect2, varscan2
- LAMA5 | c.8912G>A p.R2971Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs200879732, COSV99440065; called by muse, varscan2
- LDHA | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as rs1221880983, COSV99908243; called by muse, mutect2
- LRRK2 | c.6428G>A p.R2143H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201271001, CM081689, COSV100111097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K19 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV100208568; called by muse, mutect2, varscan2
- MAP3K7 | c.1777G>A p.E593K (on ENST00000369329 / NM_145331.3; = p.E566K on NM_003188.4) | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV65223612; called by muse, mutect2, varscan2
- MICOS10 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100503320; called by muse, mutect2
- MIGA2 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV99477613; called by muse, mutect2, varscan2
- MLXIP | c.2117C>G p.S706* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as COSV100038758; called by muse, mutect2
- MTTP | c.1862T>C p.I621T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1462140037, COSV99645165; called by muse, mutect2, varscan2
- MUSK | c.2182A>C p.T728P | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99504232; called by muse, mutect2, varscan2
- NCOR1 | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs953868639, COSV99249896; called by muse, mutect2, varscan2
- NECTIN3 | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100162429; called by muse, mutect2, varscan2
- NUTF2 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99534421; called by muse, mutect2, varscan2
- OR8B4 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100635753, COSV100635816; called by muse, mutect2
- PCDHB12 | c.593A>T p.K198M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV99507265; called by muse, mutect2, varscan2
- PCYOX1L | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99199194; called by muse, mutect2, varscan2
- PDK4 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | catalogued as COSV99138822; called by muse, mutect2, varscan2
- PLA2G4F | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99300644; called by muse, mutect2
- PODN | c.497G>A p.R166Q (on ENST00000395871; = p.R118Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs774873724, COSV100439568; called by mutect2, varscan2
- PRUNE2 | c.1697A>G p.H566R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs184556479, COSV100944569; called by muse, mutect2, varscan2
- RALGPS1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768611508, COSV52216641; called by muse, mutect2
- RASA2 | c.135T>A p.C45* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99656146; called by muse, varscan2
- RECQL4 | c.3136G>C p.E1046Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as COSV100020571, COSV56742668; called by muse, mutect2, varscan2
- ROBO2 | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV100166803; called by muse, mutect2, varscan2
- RUNX1T1 | c.91C>A p.R31S (on ENST00000265814 / NM_001198628.1; = p.R4S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.163); catalogued as COSV56153978, COSV56159553; called by muse, mutect2, varscan2
- SCIN | c.2018C>T p.S673F (on ENST00000297029 / NM_001112706.3; = p.S426F on NM_033128.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV51690483; called by muse, mutect2, varscan2
- SCN3A | c.4561G>C p.D1521H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51800371, COSV51800627; called by muse, mutect2, varscan2
- SEC61A2 | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV100036422; called by muse, mutect2, varscan2
- SMG6 | c.3708G>A p.M1236I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99558195; called by mutect2, varscan2
- SMYD3 | c.295C>T p.P99S (on ENST00000490107 / NM_001375962.1; = p.P40S on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV101194023; called by muse, mutect2, varscan2
- SYNM | c.4243G>A p.E1415K | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV100018745; called by muse, mutect2, varscan2
- TCHH | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as rs1056547811, COSV100915057; called by muse, mutect2, varscan2
- TECPR1 | c.1932C>A p.D644E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV101130501; called by muse, mutect2
- TGFBR2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55444927, COSV99847122; called by muse, varscan2
- TOP3B | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100592502; called by muse, mutect2
- TP53 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV99403779; called by muse, mutect2, varscan2
- TP53BP1 | c.3117C>G p.I1039M | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99780535; called by muse, mutect2, varscan2
- TRIP11 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as rs1181250837, COSV99970688; called by muse, mutect2
- TTC33 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs142188985, COSV100531907; called by mutect2, varscan2
- TUB | c.868C>T p.R290C (on ENST00000299506 / NM_177972.3; = p.R345C on NM_003320.4) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745847244, COSV100210210, COSV100210489; called by muse, mutect2, varscan2
- TYSND1 | c.1361C>G p.S454* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV54642687, COSV99751906; called by muse, mutect2, varscan2
- USP15 | c.552G>C p.M184I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as COSV99739543; called by muse, mutect2, varscan2
- ZBTB43 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV100991380; called by muse, mutect2, varscan2
- ZMYM6 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs148778794; called by muse, mutect2, varscan2
- ZNF214 | c.468G>C p.M156I | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53482945, COSV99547404; called by muse, mutect2, varscan2
- ZNF358 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV99900607; called by muse, mutect2
- ZNF418 | c.1255G>T p.G419C | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV101268934; called by muse, mutect2, varscan2
- ZNF615 | c.15G>A p.Q5= | Splice Region (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100943799; called by muse, mutect2, varscan2
- ZNF750 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as COSV99489772; called by muse, mutect2, varscan2
- OR4S1 | c.756del p.M253Cfs*23 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | called by mutect2, pindel, varscan2
- AC131160.1 | c.1077G>A p.K359= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV100590613; called by muse, mutect2
- ATAD3A | c.699G>A p.E233= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100186335; called by muse, mutect2, varscan2
- B4GALT7 | c.861G>A p.L287= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV99218987; called by muse, mutect2, varscan2
- BARHL1 | c.645C>T p.L215= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1193024415, COSV99707580; called by muse, mutect2
- CAMTA1 | c.2895C>T p.H965= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs748465246, COSV57885845; called by muse, mutect2, varscan2
- COL14A1 | c.225G>A p.L75= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV52864373; called by muse, mutect2
- CPVL | c.756C>T p.F252= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV99605807; called by muse, mutect2, varscan2
- DNAH2 | c.12384C>A p.T4128= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as COSV101209313; called by muse, mutect2, varscan2
- FAAP100 | c.1233C>A p.P411= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV100585371; called by muse, mutect2, varscan2
- FARP2 | c.2022C>T p.L674= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1016182357, COSV99884640; called by muse, mutect2, varscan2
- IGHV3-49 | c.267C>T p.F89= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1555534610; called by muse, mutect2, varscan2
- IGSF10 | c.1398G>A p.R466= | Silent (SNP) | VAF 32/196 reads (16%) | catalogued as rs1337903396, COSV99180016; called by muse, mutect2, varscan2
- IGSF9B | c.3681C>T p.G1227= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1370633940, COSV100317645; called by muse, mutect2, varscan2
- ITGA10 | c.2721C>A p.V907= | Silent (SNP) | VAF 56/243 reads (23%) | catalogued as COSV65196702; called by muse, mutect2, varscan2
- LHX8 | c.858T>G p.P286= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV99633743; called by muse, mutect2, varscan2
- LRP8 | c.1104C>G p.L368= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV100036477; called by muse, mutect2
- LRRC37A | c.3828C>A p.T1276= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100208179; called by muse, mutect2, varscan2
- MRPL35 | c.168C>T p.S56= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs1296167096, COSV99608004; called by muse, mutect2, varscan2
- MYH13 | c.1353C>A p.T451= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV99353985; called by muse, mutect2, varscan2
- NCK2 | c.564G>A p.L188= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV99255816; called by muse, mutect2, varscan2
- NINJ2 | c.148C>T p.L50= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99843037; called by muse, mutect2, varscan2
- NKD1 | c.1047C>A p.P349= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99194049; called by muse, mutect2
- NOD2 | c.1899C>T p.G633= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100318555; called by muse, mutect2
- NR6A1 | c.1116C>T p.L372= (on ENST00000487099 / NM_033334.4; = p.L367= on NM_001489.5) | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV100748551; called by muse, mutect2
- PCDHB6 | c.2142G>A p.R714= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV50745907; called by muse, mutect2, varscan2
- PHEX | c.441G>A p.A147= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs770726332, COSV65075622; called by muse, mutect2
- PPP2R5B | c.846G>A p.L282= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV99376140; called by muse, mutect2
- PRKG2 | c.1689A>T p.A563= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV52327792; called by muse, mutect2, varscan2
- PRSS36 | c.2190C>T p.S730= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV99191269; called by muse, mutect2
- RAP1GAP | c.876C>T p.I292= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs142966130; called by muse, mutect2, varscan2
- SLC25A32 | c.369C>T p.Y123= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99884449; called by muse, mutect2, varscan2
- SLC45A4 | c.1098C>T p.A366= (on ENST00000517878 / NM_001286646.2; = p.A315= on NM_001080431.2) | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs756433650, COSV99196594; called by muse, mutect2, varscan2
- SMOC1 | c.135C>G p.L45= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV100734591; called by muse, mutect2, varscan2
- SOGA1 | c.2127C>G p.L709= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV52929054; called by muse, mutect2, varscan2
- SYT2 | c.891C>G p.L297= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV100937136; called by muse, mutect2
- TINF2 | c.186G>A p.K62= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs750655470, COSV57468532, COSV99945495; called by muse, mutect2, varscan2
- TNXB | c.9759C>T p.T3253= (on ENST00000647633; = p.T3006= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs542220442, COSV64483258; called by muse, mutect2, varscan2
- TSPAN10 | c.384G>A p.L128= (on ENST00000574882 / NM_001290212.1; = p.L90= on NM_031945.4) | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100148538; called by muse, mutect2, varscan2
- UBR5 | c.6130C>T p.L2044= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV55289934; called by muse, mutect2
- VAV2 | c.822C>T p.L274= (on ENST00000371850 / NM_001134398.2; = p.L269= on NM_003371.4) | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1001801242, COSV100895776; called by muse, mutect2
- ZFP69 | c.1512C>T p.F504= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs369939141; called by muse, mutect2, varscan2
- AC244258.1 | n.418G>T | RNA (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668373 T>C | 5'Flank (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- CNNM3 | c.*2G>A | 3'UTR (SNP) | VAF 16/170 reads (9%) | catalogued as rs765622730, COSV100562672; called by muse, mutect2
- SNORD116-5 | n.74G>A | RNA (SNP) | VAF 10/113 reads (9%) | catalogued as rs540078148; called by muse, mutect2
